Gene-level copy-number profile of tumor specimen ALCH-B02A-TTP1-A from ALCHEMIST case ALCH-B02A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,106 days).
Specimen ALCH-B02A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f10f6ba8-0817-4562-93cd-e5b805c42b5c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B02A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/cd381c37-0caf-461f-9f77-3f68640f046e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 100; copy number 2: 15,082; copy number 3: 7,633; copy number 4: 28,225; copy number 5: 2,129; copy number 6: 2,734; copy number 7: 393; copy number 8: 550; copy number 9: 854; copy number 10: 46; copy number 11: 454; copy number 12: 160.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–4): RNU6-904P, RPS16P3.
- chr9:21,967,752–22,128,103, 7 genes (within-gene range 0–2): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:28,598,668–28,599,292, 1 gene (within-gene range 0–2): KCTD10P1.
- chr12:131,828,393–131,851,783, 1 gene: MMP17.
- chr19:5,978,403–6,020,363, 1 gene (within-gene range 0–4): AC011444.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,514 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,971,093–85,905,199, 45 genes, copy number 11: KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1.
- chr3:161,816,909–198,123,232, 632 genes, copy number 9–12 (broad region; genes not listed).
- chr12:12,310–13,219,941, 476 genes, copy number 9 (broad region; genes not listed).
- chr12:14,169,746–27,425,289, 201 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr14:18,333,726–21,014,822, 156 genes, copy number 9 (broad region; genes not listed).
- chr14:21,024,109–21,036,276, 4 genes, copy number 9 (within-gene range 2–9): TPPP2, AL161668.4, AL161668.2, RNASE13.

Autosomal genes at a single copy (total copy number 1): 100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
